Somatic mutation profile of tumor specimen MMRF_2317_1_BM_CD138pos (aliquot MMRF_2317_1_BM_CD138pos_T1_KHS5U_L11057) from MMRF case MMRF_2317, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.6 years (27,609 days).
Specimen MMRF_2317_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a4620bf-089b-40ac-918a-ad8c9967a8ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2317_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2317_1_PB_WBC_C2_KHS5U_L11058; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d913c4f-74e6-4e30-a026-e40382f254d6

The open-access MAF lists 115 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 32, Intron 15, Silent 15, Nonsense Mutation 3, 3'Flank 3, 5'Flank 2, 5'UTR 2, Frame Shift Del 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57327935, COSV99965567; called by muse, mutect2, varscan2
- ARFGEF3 | c.2872G>T p.E958* | Nonsense Mutation (SNP) | VAF 39/135 reads (29%) | catalogued as COSV52452942; called by muse, mutect2, varscan2
- C9orf135 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 55/180 reads (31%) | catalogued as rs372154813; called by muse, mutect2, varscan2
- CSMD1 | c.8704G>A p.E2902K (on ENST00000520002; = p.E2901K on NM_033225.6) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.396); catalogued as COSV59290937; called by muse, mutect2, varscan2
- CYP4X1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.373); catalogued as rs752372409, COSV64149569; called by muse, mutect2, varscan2
- DICER1 | c.5101T>C p.Y1701H | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58630585; called by muse, mutect2, varscan2
- DNAH5 | c.6628C>T p.P2210S | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759065820, COSV99443507; called by muse, mutect2, varscan2
- ENAM | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV68535908; called by muse, mutect2, varscan2
- EXT1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV65480406; called by muse, mutect2, varscan2
- GPR50 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs752426790, COSV99505627; called by muse, mutect2, varscan2
- IGHV2-70 | c.169T>C p.W57R | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs749669763; called by muse, varscan2
- IGKJ1 | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 166/522 reads (32%) | catalogued as rs549399413; called by muse, varscan2
- JADE1 | c.691C>T p.H231Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56905792; called by muse, mutect2, varscan2
- MAG | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as rs199895557, COSV62699264; called by muse, mutect2, varscan2
- MARF1 | c.4226G>A p.R1409Q | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as rs1303278737; called by muse, mutect2, varscan2
- MYO3A | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 60/361 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776262484; called by muse, mutect2, varscan2
- NOX4 | c.754C>G p.P252A | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV54449017, COSV54450270; called by muse, mutect2, varscan2
- PCLO | c.7682T>C p.L2561P | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs760552932; called by muse, mutect2, varscan2
- RNF133 | c.244del p.I82Sfs*46 | Frame Shift Del (DEL) | VAF 73/305 reads (24%) | catalogued as rs1564096745; called by mutect2, pindel, varscan2
- TRIM35 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 59/403 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.678); catalogued as rs760859895, COSV100542844; called by muse, mutect2, varscan2
- TRPM4 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs752951205; called by muse, mutect2, varscan2
- UBLCP1 | c.296T>G p.F99C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57142529; called by muse, mutect2, varscan2
- XPR1 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV62558421; called by muse, mutect2, varscan2
- ABCA7 | c.4765-2A>G p.X1589_splice | Splice Site (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- ACSL3 | c.221T>A p.L74* | Nonsense Mutation (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS15 | c.501del p.G168Efs*76 | Frame Shift Del (DEL) | VAF 25/99 reads (25%) | called by mutect2, pindel, varscan2
- AP4E1 | c.1463G>T p.R488I | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ARHGAP5 | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN13 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CCN2 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CYP2B6 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX24 | c.1421A>C p.D474A | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- DIS3 | c.1558G>T p.D520Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EZH1 | c.2069A>G p.H690R | Missense Mutation (SNP) | VAF 91/404 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GANAB | c.1942G>T p.V648L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- H3C6 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYO18A | c.1751G>C p.R584P | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MYOZ2 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PLXNA3 | c.5513G>A p.R1838H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- PRKD2 | c.1745_1750del p.I582_D583del | In Frame Del (DEL) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- RARRES1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC8A2 | c.1015A>G p.N339D | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- TMTC4 | c.2148C>G p.D716E (on ENST00000376234 / NM_001350577.2; = p.D735E on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- TRBV4-2 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM54 | c.1019C>T p.A340V (on ENST00000380075 / NM_187841.3; = p.A382V on NM_032546.4) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSPOAP1 | c.3814G>A p.E1272K | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ABCC12 | c.4050G>A p.A1350= | Silent (SNP) | VAF 114/399 reads (29%) | catalogued as rs761524398, COSV100253406, COSV60918948; called by muse, mutect2, varscan2
- CCDC68 | c.783C>T p.I261= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as COSV61604860; called by muse, mutect2, varscan2
- CHD7 | c.2451T>C p.S817= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV71109702; called by muse, mutect2
- CPXM1 | c.1971C>T p.G657= | Silent (SNP) | VAF 92/347 reads (27%) | catalogued as rs550041299, COSV101013809, COSV66045000; called by muse, mutect2, varscan2
- FKRP | c.741G>T p.P247= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs1488332243; called by muse, mutect2, varscan2
- GANC | c.2070T>A p.A690= | Silent (SNP) | VAF 55/188 reads (29%) | called by muse, mutect2, varscan2
- GRIN3A | c.2157C>T p.A719= | Silent (SNP) | VAF 56/162 reads (35%) | called by muse, mutect2, varscan2
- MYOD1 | c.654C>T p.S218= | Silent (SNP) | VAF 52/200 reads (26%) | catalogued as COSV51453945; called by muse, mutect2, varscan2
- NOX5 | c.1116C>T p.V372= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as rs775786754; called by muse, mutect2, varscan2
- NRK | c.1648C>T p.L550= | Silent (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- PSORS1C2 | c.36C>T p.V12= | Silent (SNP) | VAF 47/290 reads (16%) | catalogued as rs1396986700; called by muse, mutect2, varscan2
- SEMA5B | c.417C>T p.I139= | Silent (SNP) | VAF 50/156 reads (32%) | catalogued as rs367552115, COSV99531130; called by muse, mutect2, varscan2
- SH3KBP1 | c.1149G>A p.E383= | Silent (SNP) | VAF 47/76 reads (62%) | called by muse, mutect2, varscan2
- SOD3 | c.309G>A p.P103= | Silent (SNP) | VAF 70/228 reads (31%) | catalogued as rs368698011; called by muse, mutect2, varscan2
- TNFSF9 | c.762A>G p.E254= | Silent (SNP) | VAF 32/139 reads (23%) | called by muse, mutect2, varscan2
- ADGRF1 | c.927+102T>C | Intron (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- AMACR | c.*747T>A | 3'UTR (SNP) | VAF 121/452 reads (27%) | called by muse, mutect2, varscan2
- B4GALT1 | c.*2164C>T | 3'UTR (SNP) | VAF 5/35 reads (14%) | catalogued as rs1236614911; called by muse, mutect2, varscan2
- BLOC1S6 | c.*2028T>G | 3'UTR (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- BRAT1 | c.1395+174G>A | Intron (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- BROX | c.*747_*756del | 3'UTR (DEL) | VAF 25/96 reads (26%) | called by mutect2, pindel, varscan2
- C10orf88 | c.*111G>A | 3'UTR (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- C14orf39 | c.*453A>T | 3'UTR (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- CAMK2D | chr4:113454018 T>C | 3'Flank (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- CAMK2D | c.*40A>G | 3'UTR (SNP) | VAF 100/325 reads (31%) | catalogued as rs752358334, COSV56435363; called by muse, mutect2, varscan2
- CDCA7L | c.*169A>G | 3'UTR (SNP) | VAF 35/112 reads (31%) | called by muse, mutect2, varscan2
- CDH19 | c.*435A>G | 3'UTR (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- CDK20 | c.564-55G>T | Intron (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2
- CNGB3 | c.*1779T>A | 3'UTR (SNP) | VAF 32/129 reads (25%) | called by muse, mutect2, varscan2
- CRB1 | c.2677-390G>A | Intron (SNP) | VAF 10/228 reads (4%) | catalogued as rs1283069790, COSV66329167; called by muse, mutect2
- CRYZL1 | c.904+230G>A | Intron (SNP) | VAF 77/292 reads (26%) | called by muse, mutect2, varscan2
- CUL3 | c.*3110T>G | 3'UTR (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- CUX1 | c.*1192C>T | 3'UTR (SNP) | VAF 26/180 reads (14%) | catalogued as rs979519006; called by muse, mutect2, varscan2
- CYS1 | c.*1038T>A | 3'UTR (SNP) | VAF 73/225 reads (32%) | called by muse, mutect2, varscan2
- EXOC3L4 | chr14:103110500 A>G | 3'Flank (SNP) | VAF 37/175 reads (21%) | called by muse, mutect2, varscan2
- FABP7 | c.348+295G>A | Intron (SNP) | VAF 60/209 reads (29%) | called by muse, mutect2, varscan2
- FP565260.6 | c.*2273A>G | 3'UTR (SNP) | VAF 6/78 reads (8%) | catalogued as rs1466789100; called by muse, mutect2
- FUZ | c.492+133C>A | Intron (SNP) | VAF 41/126 reads (33%) | called by mutect2, varscan2
- GABRG1 | c.*1049C>A | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- GPR83 | c.*1097T>C | 3'UTR (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- GRIN3A | c.*3117G>A | 3'UTR (SNP) | VAF 16/100 reads (16%) | catalogued as rs1344664948; called by muse, mutect2, varscan2
- GYG2P1 | n.450+162G>A | Intron (SNP) | VAF 46/85 reads (54%) | called by muse, mutect2, varscan2
- H2AZ1 | c.196-113G>A | Intron (SNP) | VAF 53/171 reads (31%) | called by muse, mutect2, varscan2
- H3C15 | chr1:149850155 G>C | 5'Flank (SNP) | VAF 26/96 reads (27%) | catalogued as rs1553757555; called by muse, mutect2
- IL17RD | c.*3367C>G | 3'UTR (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- ILK | c.-93+53C>T | Intron (SNP) | VAF 46/434 reads (11%) | called by muse, mutect2, varscan2
- KCNT2 | c.3211+72T>A | Intron (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- KCTD16 | c.*796T>G | 3'UTR (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- LBX2 | c.*340G>A | 3'UTR (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- LEKR1 | c.*1480A>C | 3'UTR (SNP) | VAF 59/258 reads (23%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+19360A>G | Intron (SNP) | VAF 48/154 reads (31%) | called by muse, mutect2, varscan2
- LINC02253 | n.575-1361T>G | Intron (SNP) | VAF 35/246 reads (14%) | called by muse, mutect2, varscan2
- LRRC61 | c.*67C>T | 3'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- LTB | c.163-123G>A | Intron (SNP) | VAF 114/463 reads (25%) | catalogued as COSV53001730; called by muse, mutect2, varscan2
- MARCHF11 | c.*327A>C | 3'UTR (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851178 T>A | 5'Flank (SNP) | VAF 86/308 reads (28%) | catalogued as rs745654102; called by muse, varscan2
- RANBP2 | c.*197C>T | 3'UTR (SNP) | VAF 13/75 reads (17%) | catalogued as rs1313466676; called by muse, mutect2, varscan2
- RFX6 | c.*143C>A | 3'UTR (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- RGS4 | c.*1962T>A | 3'UTR (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- RIC1 | c.-13C>T | 5'UTR (SNP) | VAF 50/130 reads (38%) | catalogued as rs941719205; called by muse, mutect2, varscan2
- RPL31 | c.*200C>G | 3'UTR (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- SNAPC1 | c.*419T>G | 3'UTR (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20318787 A>G | 3'Flank (SNP) | VAF 109/429 reads (25%) | called by muse, mutect2, varscan2
- SRSF1 | c.379+90T>A | Intron (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2
- TFEC | c.*2021T>G | 3'UTR (SNP) | VAF 34/103 reads (33%) | called by muse, mutect2, varscan2
- TMEM233 | c.*966G>A | 3'UTR (SNP) | VAF 3/11 reads (27%) | catalogued as rs1227317212; called by muse, mutect2
- YIPF6 | c.*4098A>T | 3'UTR (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- ZNF804A | c.-394del | 5'UTR (DEL) | VAF 8/67 reads (12%) | called by mutect2, varscan2
- ZRANB2 | c.*127T>C | 3'UTR (SNP) | VAF 45/292 reads (15%) | called by muse, mutect2, varscan2
